Somatic mutation profile of tumor specimen TCGA-LN-A5U7-01A (aliquot TCGA-LN-A5U7-01A-11D-A31U-09) from TCGA case TCGA-LN-A5U7, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G1; Age at diagnosis: 46.3 years (16,928 days).
Specimen TCGA-LN-A5U7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc3c3622-eb12-4c19-be5f-7054fa00d57a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A5U7-10A (Blood Derived Normal), aliquot TCGA-LN-A5U7-10A-01D-A31U-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dda8c448-4102-482e-a216-d445d855746f

The open-access MAF lists 128 somatic variants for this specimen: 96 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 84, Silent 29, Splice Site 5, Nonsense Mutation 3, Frame Shift Del 2, 5'UTR 1, Intron 1, In Frame Ins 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EVC | c.703-1G>A p.X235_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as rs1485152854, CS070372; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.82_84dup p.I28dup | In Frame Ins (INS) | VAF 18/69 reads (26%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 23/26 reads (88%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTRT1 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV64420165; called by muse, mutect2, varscan2
- CADM2 | c.1169G>A p.R390Q (on ENST00000407528 / NM_001167674.2; = p.R392Q on NM_153184.4) | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67359256; called by muse, mutect2, varscan2
- CHST10 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51804564; called by muse, mutect2, varscan2
- DNAH11 | c.1990G>A p.D664N | Missense Mutation (SNP) | VAF 9/124 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV60942807; called by muse, mutect2
- DNER | c.1435C>T p.H479Y | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100519223, COSV59163050; called by muse, mutect2, varscan2
- DSCAM | c.3659G>A p.R1220Q | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs755579756, COSV68020290; called by muse, mutect2, varscan2
- ERAP1 | c.458G>C p.G153A | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as COSV57091873; called by muse, mutect2, varscan2
- GPR161 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768889642; called by muse, mutect2, varscan2
- H2BC9 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV55100448, COSV99769028; called by muse, mutect2, varscan2
- IGHV1-24 | c.329C>T p.T110M | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.606); catalogued as rs139845206; called by muse, mutect2, varscan2
- INSR | c.2180C>T p.S727L | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV57163041; called by muse, mutect2, varscan2
- LIPE | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs141806189; called by muse, mutect2, varscan2
- LRFN4 | c.1759G>A p.D587N | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs1455004025; called by muse, mutect2, varscan2
- NEK11 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as rs756935996; called by muse, varscan2
- OASL | c.23A>G p.Y8C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57477396; called by muse, mutect2
- PAPPA2 | c.4219G>C p.V1407L | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.53); PolyPhen benign (0.024); catalogued as COSV100868445; called by muse, mutect2, varscan2
- PHLPP1 | c.3605G>A p.R1202H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.93); catalogued as rs765622042; called by muse, mutect2, varscan2
- PJA2 | c.242C>G p.P81R | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1330893528, COSV63273639; called by muse, mutect2, varscan2
- PODXL2 | c.1426-1G>C p.X476_splice | Splice Site (SNP) | VAF 25/72 reads (35%) | catalogued as COSV51742103; called by muse, mutect2, varscan2
- PTH2R | c.1004A>G p.N335S | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1306960968; called by muse, mutect2, varscan2
- PTPN1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1384590527; called by muse, mutect2, varscan2
- RXFP1 | c.1091G>T p.R364I | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV57055170; called by muse, mutect2, varscan2
- SEC61A1 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 55/115 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV54575688; called by muse, mutect2, varscan2
- SLC22A9 | c.1550C>T p.P517L | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99655441; called by muse, mutect2, varscan2
- SLC7A14 | c.391G>C p.V131L | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV51589747; called by muse, mutect2, varscan2
- TDP2 | c.901A>G p.M301V | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1465620409; called by muse, mutect2, varscan2
- THSD7A | c.1355C>T p.T452M | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs767811878, COSV70260472; called by muse, mutect2, varscan2
- THSD7B | c.1335C>A p.S445R | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.038); catalogued as rs768714043; called by muse, mutect2, varscan2
- TMPRSS9 | c.2062G>A p.D688N (on ENST00000648592; = p.D654N on NM_182973.2) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.995); catalogued as rs1322378762; called by muse, mutect2
- TRIP11 | c.2764C>G p.Q922E | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775944391; called by muse, mutect2, varscan2
- WDFY3 | c.10574A>C p.N3525T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.023); catalogued as COSV55715536; called by muse, mutect2, varscan2
- WFIKKN1 | c.635G>A p.R212H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.96); catalogued as rs146880296; called by muse, varscan2
- YEATS2 | c.1559C>T p.P520L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.272); catalogued as rs748267661, COSV59371693; called by muse, mutect2, varscan2
- ZNF429 | c.86A>G p.Y29C | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764139712, COSV100641970; called by muse, mutect2, varscan2
- ZSCAN20 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs375588396; called by muse, varscan2
- ACACB | c.4583A>C p.K1528T | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- AGRN | c.3466G>T p.D1156Y | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASNS | c.389A>G p.N130S | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ATP11C | c.1837A>G p.R613G | Missense Mutation (SNP) | VAF 46/55 reads (84%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GNT2 | c.268A>G p.I90V | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2
- CFAP44 | c.2528C>G p.T843S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLTCL1 | c.2502G>C p.M834I | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- COL24A1 | c.3724C>G p.Q1242E | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- COL6A6 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL7A1 | c.2877C>A p.S959R | Missense Mutation (SNP) | VAF 15/17 reads (88%) | SIFT tolerated (0.21); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CORO2A | c.530G>A p.S177N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- DENND11 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- FBH1 | c.1270A>G p.T424A (on ENST00000362091 / NM_178150.3; = p.T475A on NM_032807.4) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2, varscan2
- GART | c.742C>G p.L248V | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- GUCD1 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- H2AC6 | c.242C>A p.P81Q | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDHD2 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- KLHL8 | c.826G>A p.V276I | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- KMO | c.1429C>G p.L477V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- KPNB1 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- LTN1 | c.1078dup p.Y360Lfs*40 | Frame Shift Ins (INS) | VAF 21/44 reads (48%) | called by mutect2, pindel, varscan2
- MAP6 | c.1990A>G p.M664V | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC17 | c.13346G>A p.G4449D | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NOS3 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- OLA1 | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OLA1 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- OLFML2B | c.1926C>G p.S642R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- OR10H4 | c.84G>C p.L28F | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4S1 | c.598A>C p.N200H | Missense Mutation (SNP) | VAF 25/105 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PAK1 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 16/32 reads (50%) | called by muse, mutect2, varscan2
- PCDH11X | c.3191G>A p.S1064N | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- PDE8B | c.787T>A p.F263I | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2
- PEAK3 | c.263G>C p.R88T | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- PLXNA1 | c.3761G>A p.G1254D | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- POGZ | c.1012del p.V338Wfs*21 | Frame Shift Del (DEL) | VAF 17/32 reads (53%) | called by mutect2, pindel, varscan2
- POLR3G | c.74A>G p.E25G | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PPP2R1B | c.206-2A>T p.X69_splice | Splice Site (SNP) | VAF 5/11 reads (45%) | called by muse, mutect2, varscan2
- PRDM9 | c.1878C>G p.H626Q | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRM | c.179A>T p.D60V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SALL2 | c.261T>A p.N87K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by mutect2, varscan2
- SALL2 | c.242_258del p.P81Qfs*2 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- SERINC1 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- SPTBN4 | c.3806G>A p.G1269D | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.014); called by mutect2, varscan2
- SPTLC2 | c.851-1G>A p.X284_splice | Splice Site (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.953A>G p.D318G | Missense Mutation (SNP) | VAF 16/38 reads (42%) | PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- TAAR5 | c.600G>T p.W200C | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- TAAR8 | c.280G>T p.E94* | Nonsense Mutation (SNP) | VAF 24/51 reads (47%) | called by muse, mutect2, varscan2
- THSD7B | c.1334G>A p.S445N | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TPTE | c.1590T>G p.D530E (on ENST00000618007 / NM_199261.4; = p.D512E on NM_199259.4) | Missense Mutation (SNP) | VAF 30/191 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TRERF1 | c.1309G>C p.A437P | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2
- TRIM49 | c.507+2T>C p.X169_splice | Splice Site (SNP) | VAF 26/132 reads (20%) | called by muse, mutect2, varscan2
- UVSSA | c.1370C>G p.P457R | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VPS37B | c.541C>T p.P181S | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- WDR90 | c.3281C>G p.S1094C | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ZFR2 | c.2517G>C p.E839D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF117 | c.561T>G p.H187Q | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- ZNF540 | c.1758G>T p.K586N | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF549 | c.158A>T p.H53L (on ENST00000376233 / NM_001199295.2; = p.H40L on NM_153263.2) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ALDH3A1 | c.300C>T p.I100= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs11554974; called by muse, varscan2
- ARSL | c.1056G>A p.S352= | Silent (SNP) | VAF 18/24 reads (75%) | catalogued as rs187110605; called by muse, mutect2, varscan2
- B3GALNT1 | c.201T>C p.L67= | Silent (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- C20orf194 | c.2940C>T p.G980= | Silent (SNP) | VAF 10/55 reads (18%) | called by muse, mutect2, varscan2
- CERCAM | c.1446G>A p.A482= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as rs776951394; called by muse, mutect2, varscan2
- CFAP97 | c.372A>G p.V124= | Silent (SNP) | VAF 36/63 reads (57%) | catalogued as rs1370397951; called by muse, mutect2, varscan2
- CLTCL1 | c.2826C>T p.S942= | Silent (SNP) | VAF 55/93 reads (59%) | catalogued as rs199728866; called by muse, mutect2, varscan2
- COL5A2 | c.1245T>A p.S415= | Silent (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- DNAJB1 | c.207G>A p.E69= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs774882978; called by muse, mutect2, varscan2
- DPY19L4 | c.834C>T p.F278= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs1257083376; called by muse, mutect2, varscan2
- FLG | c.2769T>C p.S923= | Silent (SNP) | VAF 52/207 reads (25%) | catalogued as rs757865005; called by muse, mutect2, varscan2
- GHR | c.1710A>G p.E570= | Silent (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- HSPG2 | c.6912C>T p.A2304= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs755251798, COSV65971495; called by muse, mutect2
- LRRC40 | c.12G>A p.L4= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs761124498; called by muse, mutect2, varscan2
- MFSD6 | c.456C>G p.V152= | Silent (SNP) | VAF 11/33 reads (33%) | catalogued as COSV55623582; called by muse, mutect2, varscan2
- OR2M7 | c.594T>C p.V198= | Silent (SNP) | VAF 36/127 reads (28%) | catalogued as COSV58740308; called by muse, mutect2, varscan2
- OR4C15 | c.717G>A p.E239= (on ENST00000314644; = p.E185= on NM_001001920.2) | Silent (SNP) | VAF 23/62 reads (37%) | catalogued as COSV100115834; called by muse, mutect2, varscan2
- OR9A4 | c.780G>A p.V260= | Silent (SNP) | VAF 9/28 reads (32%) | called by muse, mutect2, varscan2
- PCDHB2 | c.1863G>A p.A621= | Silent (SNP) | VAF 65/124 reads (52%) | catalogued as rs1554271581, COSV50565724; called by muse, mutect2, varscan2
- RBM6 | c.2394C>T p.Y798= | Silent (SNP) | VAF 34/91 reads (37%) | called by muse, mutect2, varscan2
- SPAST | c.228G>T p.V76= | Silent (SNP) | VAF 21/53 reads (40%) | called by muse, mutect2, varscan2
- SPDYE3 | c.1419G>A p.K473= | Silent (SNP) | VAF 49/258 reads (19%) | called by muse, mutect2, varscan2
- SPHKAP | c.69A>G p.E23= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as COSV60882995; called by muse, mutect2, varscan2
- SYT4 | c.567C>T p.T189= | Silent (SNP) | VAF 23/86 reads (27%) | called by muse, mutect2, varscan2
- VPS51 | c.1746G>A p.V582= | Silent (SNP) | VAF 30/66 reads (45%) | called by muse, mutect2, varscan2
- ZBED8 | c.930A>G p.L310= | Silent (SNP) | VAF 19/26 reads (73%) | catalogued as rs757344812, COSV101283552; called by muse, mutect2, varscan2
- ZNF222 | c.651A>G p.K217= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- ZNF233 | c.426G>A p.Q142= | Silent (SNP) | VAF 14/35 reads (40%) | called by muse, mutect2, varscan2
- ZNF454 | c.114G>C p.L38= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV60770654; called by muse, mutect2, varscan2
- BIRC6 | c.12291+632A>G | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- LINC00922 | n.588C>T | RNA (SNP) | VAF 19/82 reads (23%) | called by muse, mutect2, varscan2
- NOTCH2NLA | c.-205A>T | 5'UTR (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
